Somatic mutation profile of tumor specimen TCGA-06-0240-01A (aliquot TCGA-06-0240-01A-03D-1491-08) from TCGA case TCGA-06-0240, project TCGA-GBM (Glioblastoma Multiforme). Sex at birth: male; Vital status: Dead; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 57.3 years (20,937 days).
Specimen TCGA-06-0240-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 8eef2f13-dfca-40eb-818d-7e9d9b90194e.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-06-0240-10A (Blood Derived Normal), aliquot TCGA-06-0240-10A-01D-1491-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/1854ea18-b3b5-4142-8161-e89c1e1f0e7d

The open-access MAF lists 1 somatic variant for this specimen: 1 protein-altering or splice-affecting.
By variant classification: Missense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- RYR3 | c.10474A>G p.M3492V (on ENST00000389232; = p.M3493V on NM_001036.6) | Missense Mutation (SNP) | VAF 6/136 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.91); catalogued as COSV66788634; called by muse, mutect2
